Somatic mutation profile of tumor specimen TARGET-30-PATVSU-01A (aliquot TARGET-30-PATVSU-01A-01D) from TARGET case TARGET-30-PATVSU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 3.5 years (1,267 days).
Specimen TARGET-30-PATVSU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44a92015-09c9-4037-8d95-ebc6d41dd71e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATVSU-10A (Blood Derived Normal), aliquot TARGET-30-PATVSU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf7fec7f-a53e-4fe9-bbfd-b11a9baca235

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.3505G>A p.G1169S | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs67815019, CM070692, CM070694, COSV99867039; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MACF1 | c.21178C>T p.R7060C (on ENST00000372915; = p.R5105C on NM_012090.5) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | catalogued as COSV57107240; called by muse, mutect2
- AHNAK2 | c.16123C>A p.Q5375K | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- KMT2C | c.9030A>C p.A3010= | Silent (SNP) | VAF 45/290 reads (16%) | called by muse, mutect2, varscan2
- VEZF1 | c.*2603C>T | 3'UTR (SNP) | VAF 33/343 reads (10%) | called by muse, mutect2
